Gene-level copy-number profile of tumor specimen TCGA-A2-A04V-01A from TCGA case TCGA-A2-A04V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 39.0 years (14,250 days).
Specimen TCGA-A2-A04V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.48d99272-3117-4309-9800-25900f7c695a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A04V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0273b988-1d47-460f-aefc-94cdaabdb1ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,484; copy number 2: 51,042; copy number 3: 2,792; copy number 4: 373; copy number 5: 36; copy number 6: 93.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A04V-01A-21D-A036-01): tumor purity 0.84, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 129 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:124,644,434–124,963,165, 1 gene, copy number 5 (within-gene range 3–5): RNF217-AS1.
- chr8:1,565,509–2,035,587, 17 genes, copy number 5: DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1.
- chr8:2,076,589–2,076,640, 1 gene, copy number 5: MIR7160.
- chr8:36,784,324–40,520,158, 93 genes, copy number 6 (broad region; genes not listed).
- chr11:69,294,151–69,926,813, 17 genes, copy number 5: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.

Autosomal genes at a single copy (total copy number 1): 5,484. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
